Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7440, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7440-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) TOTAL LARYNGECTOMY:
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA WITH EXTENSIVE
PERINEURAL INVASION AND VASCULAR LYMPHATIC INVASION, INVOLVING
THE PIRIFORM SINUS AND LEFT SUPRAGLOTTIC REGION.
Margins of resection free of tumor.
- (B) LEFT BASE OF TONGUE MARGIN:
skeletal muscle, no tumor present.

GROSS DESCRIPTION

(A) TOTAL LARYNGECTOMY - A total laryngectomy specimen, 9.0 (S-I) x 6.5 (L-R) x 4.67 (A-P) cm. There is a roughened red supraglottic tumor present on the left side, involving the pyriform sinus. It appears to extend toward the midline and may cross over the midline approximately 1.0 mm. This tumor is 2.7 (M-L) x 2.5 (S-I) cm in size. There is no extension through the base of the epiglottis or the thyroid cartilage, grossly. There is no involvement of the glottic or subglottic areas. No thyroid tissue is included with this laryngectomy specimen.

INK CODE: Black - peripheral mucosal margin and anterior aspect of epiglottic remnant.

SECTION CODE: A1, anterior right mucosal margin (12-2 o'clock, en face, for frozen section); A2, right mucosal margin (2-4:30), en face for frozen; A3, posterior mucosal margin (4:30-7:30), en face; A4, left posterior mucosal margin (7-9 o'clock), en face; A5, left lateral mucosal margin (9 o'clock-10:30), en face; A6, left anterior mucosal margin (10:30-12 o'clock), en face; A7, A8, perpendicular sections of superior (12 o'clock), tissue for deep margin, frozen section; A9, sections of right true and false vocal cord; A10, left section of true and false vocal cord; A11-A15, perpendicular radial sections of the left supraglottic area, going from posterior to midline; A17, radial section, anterior midline, supraglottic area; A18-A23, radial sections of the right supraglottic area, going from midline to posterior. Reserve tissue is available.

*FS/DX: INVASIVE SQUAMOUS CELL CARCINOMA, MUCOSAL AND DEEP MARGINS, FREE OF TUMOR.

(B) LEFT BASE OF TONGUE MARGIN, INK AT TRUE MARGIN - An irregular fragment of tan soft tissue (2.9 x 1.5 x 0.4 cm). One side of the specimen is previously inked blue designating the true margin. The true margin is re-inked in black. Specimen is serially sectioned and submitted in B1 and B2, frozen section, perpendicular margin.

[page 2 of 2]
*FS/DX: SKELETAL MUSCLE, NO TUMOR PRESENT.

SNOMED CODES

M-80703 T-24100

Source: NCI Genomic Data Commons file aaf097a9-8cc4-4299-8ac9-bc67b4f15b34 (TCGA-CV-7440.97A361BE-C4FA-419F-875A-A0AD98C0FD73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).